Surgical pathology report (de-identified scan), TCGA case TCGA-KD-A5QT, project TCGA-SARC (Sarcoma), tissue source site Mount Sinai School of Medicine, specimen TCGA-KD-A5QT-01A (Primary Tumor).

1CD-0-3

Leiomyosarcoma, NOS 8890/3
Site: uterus, NOS C55.9

hw
3/29/13

Leiomyosarcoma

CATEGORY: SARCOMA—LEIOMYOSARCOMA

FROM PRIMARY GYNECOLOGIC SURGERY

CLINICAL HISTORY - Pelvic mass.

UTERUS, TUBES AND OVARIES (57g) - Inactive endometrium. Leiomyomas. Ovaries with epithelial inclusions and corpora albicantia. Left ovary with serous cystadenoma. Fallopian tubes with no diagnostic change.

CERVICAL MASS - Leiomyosarcoma with necrosis. No vascular invasion is seen. The parametrial soft tissue margin is free of tumor. Sections of the cervical resection margin pending. An addendum will follow. Addendum: The mitotic count varies in different sections of the tumor, but is as high as 102 mitotic figures per 10 HPF (slide B7). Additional sections of the cervical resection margin (B13) and the tumor with adjacent endocervix (B14-B15) show that the cervical resection margin is free of tumor.

RIGHT OBTURATOR LYMPH NODE #1 - Eight lymph nodes, no tumor seen.

PARA AORTIC LYMPH NODE #1 (RIGHT) - One lymph node, no tumor seen.

RIGHT PARA AORTIC LYMPH NODE #2 - Two lymph nodes, no tumor seen.

RIGHT PARA AORTIC LYMPH NODE #3 - Five lymph nodes, no tumor seen.

RIGHT PARA AORTIC LYMPH NODE #4 - Fibroadipose tissue, no tumor seen.

RIGHT OBTURATOR #2 - Two lymph nodes, no tumor seen.

RIGHT OBTURATOR #3 - Three lymph nodes, no tumor seen.

RIGHT OBTURATOR #4 - Fibroadipose tissue, no tumor seen.

RIGHT COMMON ILIAC #1 - Fibroadipose tissue, no tumor seen.

RIGHT COMMON ILIAC #2 - Two lymph nodes, no tumor seen.

RIGHT INTERNAL #1 - Fibroadipose tissue, no tumor seen.

RIGHT INTERNAL - Fibroadipose tissue, no tumor seen.

RIGHT INTERNAL #3 - Two lymph nodes, no tumor seen.

RIGHT EXTERNAL #1 - One lymph node, no tumor seen.

RIGHT EXTERNAL #2 - One lymph node, no tumor seen.

RIGHT EXTERNAL #3 - Fibroadipose tissue, no tumor seen.

CLOQUET RIGHT - Fibroadipose tissue, no tumor seen.

LEFT OBTURATOR #1 - Two lymph nodes, no tumor seen.

LEFT OBTURATOR #2 - One lymph node, no tumor seen.

LEFT OBTURATOR #3 - Two lymph nodes, no tumor seen.

LEFT OBTURATOR #4 - One lymph node, no tumor seen.

LEFT PARA AORTIC LYMPH NODE - One lymph node, no tumor seen.

LEFT EXTERNAL ILIAC #1 - One lymph node, no tumor seen.

LEFT EXTERNAL ILIAC #2 - One lymph node, no tumor seen.

LEFT CLOQUET #1 - Five lymph nodes, no tumor seen.

LEFT CLOQUET #2 - One lymph node, no tumor seen.

LEFT CLOQUET #3 - One lymph node, no tumor seen.

OMENTUM - Fibroadipose tissue, no tumor seen. Additional sections pending. An addendum will follow.

Addendum: Additional sections (DD2-DD4) show fibroadipose tissue, no tumor seen.

Diagnostic Discrepancy		
Data/Sync/Trans Primary/Noted		

Source: NCI Genomic Data Commons file 4072335d-fa2e-4384-b754-6a33bb1acdc2 (TCGA-KD-A5QT.103A9E70-1701-473E-926F-2AC6C2DFFF36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).